Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-A4CD, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-A4CD-01A (Primary Tumor).

[page 1 of 5]
Department of Pathology

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN: [REDACTED]		
Ordering MD: [REDACTED]		

Surgical Pathology Consultation Report

* Addended *

SPECIMEN(S) RECEIVED

1. Lymph-Node: RT. NECK ZONE 4
2. Salivary-Gland: TAIL OF RT PAROTID
3. Oral Cavity: Rt. Mandible
4. Neck: Contents Rt. neck
5. Surgical Waste

ICD - 0 - 3

carcinoma, squamous cell, Nos 8070/3
site: mandible C41.1

W 9/26/12

DIAGNOSIS

1. Right neck zone 4 lymph node.
One lymph node negative for tumor (0/1).
2. Tail of right parotid gland.
Parotid with no pathologic changes.
Three lymph nodes negative for tumor (0/3).
3. Oral cavity; right mandible.
Squamous cell carcinoma, poorly differentiated.
- a. Maximum tumor dimension 5.5 cm.
- b. Negative for perineural invasion.
- c. Negative for lymphovascular invasion.
- d. Tumor is close to multiple margins including medial posterior muscle and soft tissue resection margin (<0.1 cm), lateral posterior skeletal muscle and soft tissue resection margin (0.1 cm), medial gingival soft tissue margin (0.3 cm), posterior superior muscle resection margin (0.3 cm), posterior retromolar trigone soft tissue resection margin (0.4 cm).
- e. Forty-seven lymph nodes negative for tumor (0/47).
- f. Sections of bone are pending. An addendum report will follow.
4. Right neck contents.
Forty-three lymph nodes negative for tumor (0/43).
5. Surgical waste.
Bone, skin and soft tissue with no pathologic changes. (Gross

[page 2 of 5]
examination only)

Status: supplemental

Page: 1 of 5

Patient Name: [REDACTED]	Service: Otolaryngology	Copath #: [REDACTED]
MRN: [REDACTED]	Visit #: [REDACTED]	Collected: [REDACTED]
DOB: [REDACTED]	Location:	Resulted: [REDACTED]
Gender: [REDACTED]	Facility:	
HCN:		
Ordering MD: [REDACTED]		

SYNOPTIC DATA

Specimen:	Mandible
Received:	Fresh
Procedure:	Mandibulectomy: Right
neck dissection	Neck (lymph node) dissection: Right
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 8.0 cm
	Additional dimension: 7.6 cm
	Additional dimension: 4.5 cm
Specimen Laterality:	Right
Tumor Site:	Mandible
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 5.5 cm
	Additional dimension: 4.1 cm
	Additional dimension: 4.0 cm
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G3: Poorly differentiated
Margins:	Margins uninvolved by invasive
carcinoma	Distance from closest margin: 0.1 cm
tissue margin	Margin(s): medial posterior soft
is not applicable	Margin status for carcinoma in situ
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT4a: Moderately advanced local

[page 3 of 5]
disease. Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose. Oral cavity: Tumor invades adjacent structures only
Regional Lymph Nodes (pN): pN0: No regional lymph node metastasis

examined: 47

Number of regional lymph nodes

Status: supplemental

Page: 2 of 5

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location: [REDACTED]
Facility: [REDACTED]

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

involved: 0

Number of regional lymph nodes

Distant Metastasis (pM):

Not applicable

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY
ORAL CANCER

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "right neck zone 4". It consists of one lymph node measuring 0.4 x 0.3 x 0.2 cm. The specimen is submitted in toto.

1A specimen bisected and submitted in toto

2. The specimen is labeled with the patient's name and as "tail of right parotid". It consists of 2 pieces of parotid measuring 2.5 x 2 x 0.8 cm and 3 x 1.5 x 1 cm. Three lymph nodes are identified ranging in size from 0.3 to 0.8 cm.

2A parotid gland

2B two lymph nodes

[page 4 of 5]
3. The specimen is labeled with the patient's name and as "right mandible". It consists of a segment of mandible with ramus measuring 7.6 AP x 8 SI x 4.5 ML cm. It includes 3 teeth. There is a tumor arising in the retromolar trigone. The tumor measures 5.5 AP x 4 SI x 4.1 ML cm. The tumor partially surrounds the first and second molar in both lateral and medial gingiva, it extends through the retromolar trigone mucosa posteriorly towards the medial and lateral skeletal muscles tissue. There is involvement of mandible bone by the tumour. The tumor is located at 0.1 cm from the closest posterior lateral and medial muscle resection margin. Remaining margins are as follows: anterior gingival resection margin, 0.7 cm each from the lateral and medial gingiva resection margin, 0.5 cm from the posterior retromolar trigone resection margin, 0.6 cm

Status: supplemental

Page: 3 of 5

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath # [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

from the posterior superior soft tissue muscle resection margin.
Representative sections are submitted.

- 3A posterior retromolar trigone mucosa resection margin with tumor
- 3B anterior gingiva mucosa resection margin
- 3C lateral gingival resection margin with tumor
- 3D medial gingival resection margin with tumor
- 3E lateral posterior skeletal muscle resection margin
- 3F medial posterior skeletal muscle resection margin
- 3G-3H tumor
- 3I posterior superior muscle resection margin
- 3J tumor and bone (decalcification)
- 3K anterior mandible resection margin (decalcification)
- 3L posterior mandible resection margin (decalcification)

4. The specimen is labeled with the patient's name and as "contents right neck". It consists of an oriented left neck dissection with overall dimensions of 9 x 8 x 1.5 cm. The internal jugular vein is not identified. The sternocleidomastoid is also not present. The submandibular gland measures 5 x 2 x 2.2cm and is unremarkable. Multiple lymph nodes ranging from 0.2 to 1.9 x 1.1 x 0.5cm are identified in multiple levels. Representative sections are submitted.

- 4A submandibular gland

[page 5 of 5]
4B level 1 multiple lymph nodes
4C level 1, 1 lymph node bisected
4D level 2, one lymph node bisected
4E-4F level 2 multiple lymph nodes
4G-4I level 3 multiple lymph nodes
4J level 3, 1 lymph node bisected
4K level 3, 2 lymph nodes

5. The specimen is labeled with the patient's name and as "surgical waste". It consists of 2 pieces of unremarkable bone the largest measuring 1.2 x 1.9 x 1.3 cm, 2 pieces of unremarkable skin the largest measuring 3.7 x 2.5 x 0.4 cm. and 3 pieces of soft tissue to skeletal muscles the largest of which measures 6 x 2.4 x 3 cm. No sections are submitted.

Addendum Status: Signed Out
Date Reported:

Status: supplemental

Page: 4 of 5

Patient Name: [REDACTED]
MRN: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
HCN: [REDACTED]
Ordering MD: [REDACTED]

Service: Otolaryngology
Visit #: [REDACTED]
Location:
Facility:

Copath #: [REDACTED]
Collected: [REDACTED]
Resulted: [REDACTED]

Addendum Comment

Decalcified sections of the mandible confirm invasion of bone by squamous cell carcinoma. The bone margins are negative for tumor.

Major Discrepancy		✓
Prior Malignant History		✓

8/28/12

Source: NCI Genomic Data Commons file 86ba17d7-6bcb-4f60-be74-225a86302e8e (TCGA-CQ-A4CD.7D4BC5FE-771F-47A7-AAAF-65CE4F13E874.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).